Gene-level copy-number profile of tumor specimen TCGA-2G-AAH0-01A from TCGA case TCGA-2G-AAH0, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.5 years (11,123 days).
Specimen TCGA-2G-AAH0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.5bf8745f-80ba-40da-b1c4-6e316121cf49.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAH0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5bfece52-62b7-436a-b917-6b9d8ffe69e0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 14,647; copy number 3: 24,250; copy number 4: 12,903; copy number 5: 6,383; copy number 6: 335; copy number 7: 257; copy number 9: 963; copy number 10: 3; copy number 13: 8; copy number 14: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAH0-01A-11D-A42X-01): tumor purity 0.46, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,301 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:192,167,786–192,957,713, 1 gene, copy number 7 (within-gene range 4–7): AL390957.1.
- chr1:192,517,190–202,341,980, 151 genes, copy number 7 (broad region; genes not listed).
- chr8:52,939,182–72,470,972, 297 genes, copy number 7–14 (broad region; genes not listed).
- chr8:72,618,722–72,661,470, 2 genes, copy number 7: HAUS1P3, AC013562.2.
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
